CCDI case PBCHVN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/5a329e43-38e0-4e8a-bb46-f68bc48b2243

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Desmoplastic fibroma: ICD-O-3 morphology code: 8823/0; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 16.9 years (6,177 days).

Biospecimens (3 samples)
- Sample 0DSP22: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSP2C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DSP2H: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
